Surgical pathology report (de-identified scan), TCGA case TCGA-69-8253, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Washington University - Cleveland Clinic, specimen TCGA-69-8253-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

De-Identified Specimen Code: [REDACTED]

Patient Age/Sex [REDACTED] F

SPECIMEN SUBMITTED:

Part A: RIGHT SUPERIOR SEGMENT

Part B: R11 SUMP

Part C: R7

Part D: R11 NODE

Final Diagnosis

1. Right lung, superior segment, segmentectomy (A) - Adenocarcinoma, micropapillary predominant (WHO mixed adenocarcinoma, with micropapillary, acinar and bronchioloalveolar cell carcinoma components), see comment.
- Centrilobular emphysema.
2. Lymph nodes, R11 SUMP, excision (B) - Metastatic adenocarcinoma.
3. Lymph nodes, R7, R11, excision (C) - Lymph nodes; negative for neoplasm.

Diagnosis Comment:

Tumor Location: right lower lobe, superior segment

Tumor Size: 2 x 2 x 1 cm

Vascular Invasion: not identified

Lymphatic Invasion: present

Bronchial Margin: negative

Vascular Margin: negative

Parenchymal Margins: negative

Pleura/Soft Tissue Margin: negative

Pathologic Stage (AJCC): p stage IIA (T1a N1 MX)

Additional comments: the adenocarcinoma is composed of micropapillary (65%), acinar (30%) and lepidic patterns (5%).

[page 2 of 2]
SURGICAL PATHOLOGY REPORT

Intraoperative Diagnosis:

1. Adenocarcinoma. Bronchial margin is negative for tumor

Clinical Diagnosis:

LUNG CA

Gross Description:

A. Received fresh for frozen section consultation is a specimen labeled "right superior segment" that consists of a wedge shaped piece of lung parenchyma weighing 58 grams and measuring 8.5 x 4.5 x 2.5 cm with a bronchial stump of 0.3 cm in length and 0.5 cm in diameter. A tan-gray solid nodule with stellate borders measuring 2 x 2 x 1 cm is present within the lung parenchyma, adjacent and retracting the overlying pleura and extending within 1.5 cm of the bronchial and 1.7 cm from the nearest parenchymal margin. The remaining lung parenchyma appears red and soft. No peribronchial lymph nodes are present. Representative sections are submitted as follows: A1 bronchial shave margin frozen, A2 - A8 nodule (A2 for frozen section evaluation, A3 with pleura, with parenchymal margin), A9 of unremarkable parenchyma distal to mass, A10 vascular margin.

B. Received fresh on Telfa gauze labeled "R11 stump" is an irregular-shaped segment of red-gray soft tissue measuring 1.3 x 0.5 x 0.4 cm. The specimen is totally submitted in formalin in one cassette.

C. Received fresh on Telfa gauze labeled "R7" is an irregular-shaped segment of red-gray soft tissue measuring 0.8 x 0.5 x 0.4 cm. The specimen is totally submitted in formalin in one cassette.

D. Received fresh on Telfa gauze labeled "R11 node" is an irregular-shaped segment of red-gray soft tissue measuring 0.4 x 0.4 x 0.4 cm. The specimen is totally submitted in formalin in one cassette.

Microscopic:

{Not Entered}

Source: NCI Genomic Data Commons file 2bfac88b-3cad-411e-b952-566e32b3c421 (TCGA-69-8253.8148140F-8B78-4C05-A2FA-59A25CC6C9D8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).